Somatic mutation profile of tumor specimen TCGA-04-1331-01A (aliquot TCGA-04-1331-01A-01W-0486-08) from TCGA case TCGA-04-1331, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 79.0 years (28,848 days).
Specimen TCGA-04-1331-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 943c7f04-dcd0-4fc7-ab7f-2d1669be0218.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-04-1331-10A (Blood Derived Normal), aliquot TCGA-04-1331-10A-01W-0486-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7455ac79-76be-426c-971a-f0fc9a1b95c2

The open-access MAF lists 130 somatic variants for this specimen: 106 protein-altering or splice-affecting, 24 silent.
By variant classification: Missense Mutation 85, Silent 24, Frame Shift Del 6, Nonsense Mutation 6, Frame Shift Ins 5, Splice Site 3, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA2 | c.2133C>A p.C711* | Nonsense Mutation (SNP) | VAF 41/50 reads (82%) | catalogued as rs535547513, COSV66461934; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.4330A>G p.K1444E (on ENST00000358273 / NM_001042492.3; = p.K1423E on NM_000267.3) | Missense Mutation (SNP) | VAF 88/116 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs137854550, CM143401, CM145726, CM920506, COSV62204136, COSV62222725; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 243/326 reads (75%) | hotspot (GDC flag); catalogued as rs121913344, CM971506, COSV52662281, COSV52987117, COSV53852813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB8 | c.386G>A p.G129E (on ENST00000297504 / NM_001282291.2; = p.G112E on NM_007188.5) | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52508086, COSV52509930; called by muse, mutect2, varscan2
- ACTRT1 | c.691C>T p.R231C | Missense Mutation (SNP) | VAF 137/315 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs749902150, COSV64419079; called by muse, mutect2, varscan2
- AHNAK2 | c.1288G>C p.E430Q | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.028); catalogued as COSV60929251; called by muse, mutect2, varscan2
- AZI2 | c.965A>G p.N322S | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.174); catalogued as rs144724369; called by muse, mutect2
- BAG3 | c.415C>T p.R139W | Missense Mutation (SNP) | VAF 61/149 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as rs556465096, COSV64842531; ClinVar: uncertain significance / benign; called by muse, mutect2, varscan2
- BRPF1 | c.1623C>G p.H541Q | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.186); catalogued as COSV57407635; called by muse, mutect2, varscan2
- C2orf78 | c.1500G>C p.R500S | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.396); catalogued as COSV68519257; called by muse, mutect2, varscan2
- CA12 | c.449A>C p.N150T | Missense Mutation (SNP) | VAF 72/92 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51607933; called by muse, mutect2, varscan2
- CCDC102A | c.734C>A p.T245K | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.85); PolyPhen benign (0.013); catalogued as COSV50779352; called by muse, mutect2, varscan2
- CCN4 | c.488dup p.R164Afs*18 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | catalogued as rs773550125; called by mutect2, pindel
- CD34 | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 24/452 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375699533; called by muse, mutect2
- CDX2 | c.916dup p.V306Gfs*31 | Frame Shift Ins (INS) | VAF 8/38 reads (21%) | catalogued as rs773511514; called by mutect2, varscan2
- CEP290 | c.3414T>G p.I1138M | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.911); catalogued as COSV100469751; called by muse, varscan2
- CHUK | c.1513del p.E505Kfs*4 | Frame Shift Del (DEL) | VAF 36/144 reads (25%) | catalogued as COSV64917647; called by pindel, varscan2
- COL15A1 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 36/64 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as rs1355684458, COSV66641761; called by muse, mutect2, varscan2
- COL4A1 | c.3658C>A p.Q1220K | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.937); catalogued as COSV101011554; called by muse, mutect2
- COL9A1 | c.1054C>T p.R352C | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1302609073, COSV57892528; called by muse, mutect2, varscan2
- CPOX | c.677G>T p.G226V | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV51639671; called by muse, mutect2, varscan2
- CPSF2 | c.1329G>T p.M443I | Missense Mutation (SNP) | VAF 64/158 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV54100558; called by muse, mutect2, varscan2
- CSAD | c.1135C>T p.R379W (on ENST00000444623 / NM_001244705.2; = p.R406W on NM_015989.5) | Missense Mutation (SNP) | VAF 83/192 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1004198719, COSV57244760; called by muse, mutect2, varscan2
- DDIT3 | c.74T>G p.L25R | Missense Mutation (SNP) | VAF 53/191 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56258463; called by muse, mutect2, varscan2
- DOCK5 | c.2400G>T p.M800I | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV52410651; called by muse, mutect2, varscan2
- DPP6 | c.1384C>T p.H462Y (on ENST00000377770 / NM_001364500.2; = p.H400Y on NM_001936.5) | Missense Mutation (SNP) | VAF 12/224 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100127962; called by muse, mutect2
- DSEL | c.3428T>A p.F1143Y | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.431); catalogued as COSV59494449; called by muse, mutect2, varscan2
- DSEL | c.137C>T p.T46I | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.299); catalogued as rs1379834042, COSV59492683; called by muse, mutect2, varscan2
- EMILIN2 | c.734C>A p.T245K | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.601); catalogued as COSV54427206; called by muse, mutect2, varscan2
- EMSY | c.1243G>C p.V415L | Missense Mutation (SNP) | VAF 20/159 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58265575; called by muse, mutect2, varscan2
- ERICH3 | c.1997A>C p.E666A | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.492); catalogued as COSV58617224; called by muse, mutect2, varscan2
- FAM166A | c.418C>G p.P140A | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.283); catalogued as COSV61118887; called by muse, mutect2
- FAM47C | c.2458G>A p.G820R | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.91); PolyPhen benign (0.183); catalogued as rs868974956, COSV63730150; called by muse, mutect2, varscan2
- FBXO21 | c.1444A>T p.K482* (on ENST00000330622 / NM_033624.3; = p.K475* on NM_015002.3) | Nonsense Mutation (SNP) | VAF 451/832 reads (54%) | catalogued as COSV100401859; called by muse, mutect2, varscan2
- FCRL5 | c.197T>G p.I66R | Missense Mutation (SNP) | VAF 94/362 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.066); catalogued as COSV62519743; called by muse, mutect2, varscan2
- FGD1 | c.2452G>T p.A818S | Missense Mutation (SNP) | VAF 53/144 reads (37%) | SIFT tolerated (0.66); PolyPhen benign (0.029); catalogued as rs1338280643, COSV64309590; called by muse, mutect2, varscan2
- FIP1L1 | c.725G>C p.G242A | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100184699; called by muse, mutect2, varscan2
- FLG2 | c.643C>A p.P215T | Missense Mutation (SNP) | VAF 16/342 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.142); catalogued as COSV101166188; called by muse, mutect2
- GRAMD1B | c.1243C>T p.P415S | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.895); catalogued as rs1406577746, COSV59210281; called by muse, mutect2, varscan2
- HACE1 | c.340A>G p.M114V | Missense Mutation (SNP) | VAF 43/53 reads (81%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.685); catalogued as COSV53507594; called by muse, mutect2, varscan2
- HECTD4 | c.12015G>T p.E4005D | Missense Mutation (SNP) | VAF 55/71 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV66399329; called by muse, mutect2, varscan2
- HLX | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV65044745; called by muse, mutect2, varscan2
- HSPA12B | c.658C>T p.R220W | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1208377353, COSV99654217; called by muse, mutect2
- KDM5C | c.2735G>A p.G912E | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.219); catalogued as rs1556837523, COSV64766205; called by muse, mutect2, varscan2
- KIAA1109 | c.14707T>C p.S4903P | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.8); catalogued as COSV52690618; called by muse, mutect2, varscan2
- KLHL38 | c.1038G>C p.R346S | Missense Mutation (SNP) | VAF 24/335 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV100384569; called by muse, mutect2
- KLHL7 | c.1670C>G p.A557G (on ENST00000339077 / NM_001031710.3; = p.A509G on NM_018846.5) | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV59164360; called by muse, mutect2, varscan2
- KRT6A | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 86/266 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.597); catalogued as rs376821206; called by muse, mutect2, varscan2
- LATS1 | c.3059G>C p.R1020T | Missense Mutation (SNP) | VAF 212/269 reads (79%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV53599295; called by muse, mutect2, varscan2
- LONRF1 | c.1280A>C p.K427T | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101238260; called by muse, mutect2, varscan2
- LRP2 | c.6890T>C p.L2297S | Missense Mutation (SNP) | VAF 48/461 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55572053; called by muse, mutect2, varscan2
- LRP2 | c.787G>A p.V263I | Missense Mutation (SNP) | VAF 263/611 reads (43%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs748432854, COSV55572064, COSV99790445; called by muse, mutect2, varscan2
- LRRC41 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 203/558 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs773606541, COSV58442315; called by muse, mutect2, varscan2
- LRRK2 | c.2485T>A p.L829I | Missense Mutation (SNP) | VAF 75/182 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.075); catalogued as COSV100111081; called by muse, mutect2, varscan2
- LZTS2 | c.572C>G p.S191C | Missense Mutation (SNP) | VAF 74/87 reads (85%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.712); catalogued as COSV64652884; called by muse, mutect2, varscan2
- MAP2 | c.100C>A p.Q34K | Missense Mutation (SNP) | VAF 173/295 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as COSV52306755; called by muse, mutect2, varscan2
- MAP4K3 | c.586G>A p.D196N | Missense Mutation (SNP) | VAF 213/532 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55717947; called by muse, mutect2, varscan2
- MAP4K3 | c.374A>G p.Y125C | Missense Mutation (SNP) | VAF 92/172 reads (53%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.91); catalogued as COSV99811068; called by muse, mutect2, varscan2
- MFAP3L | c.563A>C p.E188A | Missense Mutation (SNP) | VAF 27/364 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV100852710; called by muse, mutect2
- MKX | c.539G>T p.G180V | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV65393230; called by muse, mutect2, varscan2
- MROH2B | c.1367C>A p.T456N | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.964); catalogued as rs746281100, COSV68186680; called by muse, mutect2, varscan2
- MYLK | c.2069C>T p.T690M | Missense Mutation (SNP) | VAF 166/372 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs368417112; ClinVar: uncertain significance; called by muse, varscan2
- MYO18B | c.6500G>T p.R2167M | Missense Mutation (SNP) | VAF 18/658 reads (3%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.639); catalogued as COSV100125063; called by muse, mutect2
- NEDD4 | c.482C>A p.S161Y | Missense Mutation (SNP) | VAF 158/220 reads (72%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.994); catalogued as COSV59066256; called by muse, mutect2, varscan2
- NEU2 | c.255G>C p.M85I | Missense Mutation (SNP) | VAF 20/622 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52091889, COSV99290743; called by muse, mutect2
- NOL4 | c.1156G>A p.D386N | Missense Mutation (SNP) | VAF 58/982 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV99308242; called by muse, mutect2
- NOP56 | c.643C>T p.Q215* | Nonsense Mutation (SNP) | VAF 40/119 reads (34%) | catalogued as COSV61391414; called by muse, mutect2, varscan2
- NTNG1 | c.261G>A p.M87I | Missense Mutation (SNP) | VAF 407/987 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1380820016, COSV53987019; called by muse, mutect2, varscan2
- OR2M2 | c.432G>A p.M144I | Missense Mutation (SNP) | VAF 85/965 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.084); catalogued as rs753762011, COSV62897737, COSV62898876; called by muse, mutect2
- PCLO | c.12961G>A p.A4321T | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.082); catalogued as COSV61639457, COSV61678580; called by muse, mutect2, varscan2
- PGLYRP3 | c.686C>A p.S229Y | Missense Mutation (SNP) | VAF 198/524 reads (38%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.921); catalogued as COSV51950783, COSV51952657; called by muse, mutect2, varscan2
- PIF1 | c.1832A>G p.Y611C | Missense Mutation (SNP) | VAF 52/72 reads (72%) | SIFT deleterious (0.03); PolyPhen benign (0.21); catalogued as COSV99165221; called by muse, mutect2, varscan2
- PLOD3 | c.876dup p.Q293Afs*48 | Frame Shift Ins (INS) | VAF 11/72 reads (15%) | catalogued as rs746342377; called by mutect2, varscan2
- PRICKLE2 | c.557G>A p.C186Y (on ENST00000295902; = p.C130Y on NM_198859.4) | Missense Mutation (SNP) | VAF 171/541 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99898012; called by muse, mutect2, varscan2
- PRKAR2A | c.720C>G p.I240M | Missense Mutation (SNP) | VAF 32/660 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99605482; called by muse, mutect2
- RAD50 | c.1293G>C p.E431D | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as COSV54757262; called by mutect2, varscan2
- RFX7 | c.1301dup p.T435Nfs*16 (on ENST00000559447 / NM_001368074.1; = p.T532Nfs*16 on NM_022841.7 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 5/44 reads (11%) | catalogued as rs1446187716; called by mutect2, pindel, varscan2
- RRP9 | c.132G>T p.K44N | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.164); catalogued as COSV51756346; called by muse, mutect2, varscan2
- SIRT2 | c.541G>T p.E181* | Nonsense Mutation (SNP) | VAF 10/258 reads (4%) | catalogued as COSV99979595; called by muse, mutect2
- SORCS2 | c.2105G>A p.R702Q | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.072); catalogued as rs746905423, COSV61182500; called by muse, mutect2
- STK36 | c.2431G>T p.G811C | Missense Mutation (SNP) | VAF 245/1790 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV55330250; called by muse, mutect2, varscan2
- SYT15 | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs782088585, COSV65431555; called by muse, mutect2, varscan2
- SYTL4 | c.1427A>T p.H476L | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.134); catalogued as COSV52171482; called by muse, mutect2, varscan2
- TACC2 | c.7886C>T p.A2629V (on ENST00000334433; = p.A707V on NM_006997.4) | Missense Mutation (SNP) | VAF 18/270 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.023); catalogued as rs150511831; called by muse, mutect2
- TBL1XR1 | c.281C>G p.T94R | Missense Mutation (SNP) | VAF 21/147 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.006); catalogued as COSV61792683; called by muse, mutect2, varscan2
- TENT4A | c.1562C>G p.S521C | Missense Mutation (SNP) | VAF 239/465 reads (51%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.528); catalogued as COSV50094912, COSV50100243; called by muse, mutect2, varscan2
- TNPO3 | c.856C>T p.R286C | Missense Mutation (SNP) | VAF 377/850 reads (44%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.838); catalogued as rs745576236, COSV99602998; called by muse, mutect2, varscan2
- TRPC7 | c.629A>T p.D210V | Missense Mutation (SNP) | VAF 22/26 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs565522086, COSV61456456, COSV61462249; called by muse, mutect2, varscan2
- TTN | c.54586C>T p.P18196S (on ENST00000591111; = p.P10772S on NM_003319.4) | Missense Mutation (SNP) | VAF 174/484 reads (36%) | PolyPhen benign (0.121); catalogued as COSV60319072; called by muse, mutect2, varscan2
- VGLL3 | c.938G>T p.G313V | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV101264171, COSV68207507; called by muse, mutect2, varscan2
- WNT7A | c.513G>T p.E171D | Missense Mutation (SNP) | VAF 191/289 reads (66%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV53198997, COSV53201911; called by muse, mutect2, varscan2
- YIF1A | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV100268552; called by muse, mutect2
- ZDHHC15 | c.118G>A p.V40I | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as COSV64903632; called by muse, mutect2, varscan2
- C18orf25 | c.92_93del p.E31Gfs*37 | Frame Shift Del (DEL) | VAF 51/208 reads (25%) | called by mutect2, pindel, varscan2
- CHUK | c.1521G>T p.M507I | Missense Mutation (SNP) | VAF 46/144 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.138); called by muse, varscan2
- DBN1 | c.239dup p.Y80* | Nonsense Mutation (INS) | VAF 58/158 reads (37%) | called by pindel, varscan2
- EPX | c.1181del p.E394Gfs*9 | Frame Shift Del (DEL) | VAF 72/526 reads (14%) | called by mutect2, pindel*, varscan2
- MAPK3 | c.544-4_546del p.X182_splice | Splice Site (DEL) | VAF 6/49 reads (12%) | called by mutect2, pindel
- MIB1 | c.532_538del p.X178_splice | Splice Site (DEL) | VAF 36/118 reads (31%) | called by mutect2, pindel, varscan2
- NCOA5 | c.462_476del p.R155_G159del | In Frame Del (DEL) | VAF 44/154 reads (29%) | called by mutect2, pindel, varscan2
- NEB | c.988dup p.T330Nfs*5 | Frame Shift Ins (INS) | VAF 14/37 reads (38%) | called by mutect2, pindel, varscan2
- STK36 | c.2278_2293del p.E760Sfs*19 | Frame Shift Del (DEL) | VAF 270/1525 reads (18%) | called by mutect2, pindel, varscan2
- THRA | c.325_343delinsAA p.L109Kfs*14 | Frame Shift Del (DEL) | VAF 71/111 reads (64%) | called by pindel, varscan2*
- TRAV9-1 | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- UNC45B | c.2380-23_2390del p.X794_splice | Splice Site (DEL) | VAF 13/92 reads (14%) | called by mutect2, pindel
- VARS2 | c.1453del p.Q485Rfs*55 | Frame Shift Del (DEL) | VAF 13/48 reads (27%) | called by mutect2, pindel, varscan2
- ABHD13 | c.669A>G p.P223= | Silent (SNP) | VAF 240/285 reads (84%) | catalogued as rs781312856, COSV65535439; called by muse, mutect2, varscan2
- ACTN4 | c.861C>A p.V287= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV53150186; called by muse, varscan2
- ALOXE3 | c.444C>T p.I148= | Silent (SNP) | VAF 20/98 reads (20%) | catalogued as COSV59077828; called by muse, mutect2, varscan2
- CAPRIN2 | c.240G>A p.G80= | Silent (SNP) | VAF 31/72 reads (43%) | catalogued as rs1405269442, COSV51835270; called by muse, mutect2, varscan2
- CSRNP1 | c.945T>A p.P315= | Silent (SNP) | VAF 39/80 reads (49%) | catalogued as COSV56189807; called by muse, mutect2, varscan2
- FAM83B | c.2202T>A p.T734= | Silent (SNP) | VAF 13/146 reads (9%) | catalogued as COSV100174981; called by muse, mutect2
- FAM83D | c.1419C>T p.S473= | Silent (SNP) | VAF 11/114 reads (10%) | catalogued as rs902310409, COSV54159062; called by muse, mutect2, varscan2
- FEZ1 | c.51C>G p.P17= | Silent (SNP) | VAF 39/49 reads (80%) | catalogued as COSV54031686; called by muse, mutect2, varscan2
- FLYWCH2 | c.384C>T p.N128= | Silent (SNP) | VAF 15/17 reads (88%) | catalogued as rs1426285295, COSV53559770; called by muse, mutect2, varscan2
- HEATR5A | c.5520G>C p.V1840= | Silent (SNP) | VAF 11/137 reads (8%) | catalogued as COSV101120496; called by muse, mutect2
- KCNK17 | c.405C>T p.F135= | Silent (SNP) | VAF 128/378 reads (34%) | catalogued as rs1380084550, COSV64686359; called by muse, mutect2, varscan2
- LLPH | c.189A>G p.Q63= | Silent (SNP) | VAF 95/250 reads (38%) | catalogued as rs746148181, COSV99874567; called by mutect2, varscan2
- NCOA7 | c.2115A>C p.T705= | Silent (SNP) | VAF 340/443 reads (77%) | catalogued as COSV57660135; called by muse, mutect2, varscan2
- NDUFAF2 | c.48A>T p.S16= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as COSV54018125; called by muse, mutect2
- NEK8 | c.1116A>G p.A372= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV52048599; called by muse, mutect2, varscan2
- PASD1 | c.1173G>C p.L391= | Silent (SNP) | VAF 26/566 reads (5%) | catalogued as COSV100949063, COSV100949587; called by muse, mutect2
- POLA1 | c.4134A>G p.T1378= | Silent (SNP) | VAF 32/257 reads (12%) | catalogued as COSV100985765; called by muse, mutect2, varscan2
- RIMS3 | c.777C>A p.I259= | Silent (SNP) | VAF 14/284 reads (5%) | catalogued as COSV101013580, COSV65504463; called by muse, mutect2
- SLC12A5 | c.2733C>T p.V911= (on ENST00000454036 / NM_001134771.2; = p.V888= on NM_020708.5) | Silent (SNP) | VAF 30/972 reads (3%) | catalogued as rs1053574223, COSV54800268, COSV54801409; called by muse, mutect2
- SLC6A11 | c.474G>C p.L158= | Silent (SNP) | VAF 6/100 reads (6%) | catalogued as COSV99594982; called by muse, mutect2
- SPRING1 | c.369C>T p.G123= | Silent (SNP) | VAF 112/285 reads (39%) | catalogued as COSV54339837; called by muse, mutect2, varscan2
- SSX2IP | c.735T>C p.G245= | Silent (SNP) | VAF 105/258 reads (41%) | catalogued as COSV60554551; called by muse, mutect2, varscan2
- TNS3 | c.3144A>T p.S1048= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as COSV60798673; called by muse, mutect2, varscan2
- TRIO | c.1200C>G p.R400= | Silent (SNP) | VAF 201/1052 reads (19%) | catalogued as COSV60080953, COSV60094586; called by muse, mutect2, varscan2
